Surgical pathology report (de-identified scan), TCGA case TCGA-05-4395, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4395-01A (Primary Tumor).

Main diagnosis/diagnoses:

Locally advanced and evidently primarily peripheral bronchopulmonary, histologically mixed, highly mucigenous adenocarcinoma of the left upper lobe of the lung with predominant large-cell and polymorphocellular solid and small acinar component, located in the boundary region of segments 1 and 3.

TNM classification pT4 pN2 V1 RX, stage IIIB

C 34.1 M 8255/3

Comment/supplementary remark:

The tumor is obviously primarily peripheral in location, has focally infiltrated the parietal layer in the region of the pleural adhesion zone located over the tumor and is possibly extending in a continuous perivascular sleeve into the hilum of the superior lobe, where it has formed a further relatively large manifestation involving parabronchial lymph nodes. A separate satellite focus can also be found in S3. The central tumor manifestation has infiltrated the pulmonary venous wall and extends at least very close in the fatty tissue to the hilar resection margin. Because of the tangential section, it cannot be definitely decided whether the tumor infiltrate found next to the resection surface actually forms the margin, hence RX. A further lymph node metastasis can be found in sample 3.). The resection margins of bronchus and vessels, the pericardial specimen also removed and the lymph nodes of samples 4.) and 5.) are tumor-free.

Source: NCI Genomic Data Commons file 5d5accd7-5cd4-4f6f-91bc-2ed8a23a5ba8 (TCGA-05-4395.601B48CA-E99C-4D4B-854E-4AA923B63237.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).